Gene-level copy-number profile of tumor specimen TCGA-DX-A3M1-01A from TCGA case TCGA-DX-A3M1, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 79.2 years (28,932 days).
Specimen TCGA-DX-A3M1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.ce61b491-98f1-497f-9c25-4c453e98c6ca.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A3M1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 824 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3991215b-7511-4411-a746-5941419186cf

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 69; copy number 1: 1,248; copy number 2: 8,729; copy number 3: 9,806; copy number 4: 33,951; copy number 5: 3,893; copy number 6: 1,203; copy number 7: 357; copy number 8: 21; copy number 9: 103; copy number 10: 90; copy number 11: 17; copy number 12: 21; copy number 14: 6; copy number 15: 7; copy number 16: 45; copy number 17: 2; copy number 18: 2; copy number 19: 17; copy number 20: 7; copy number 21: 3; copy number 22: 9; copy number 23: 3; copy number 24: 10; copy number 25: 14; copy number 27: 10; copy number 28: 10; copy number 29: 61; copy number 30: 28; copy number 31: 9; copy number 32: 1; copy number 34: 9; copy number 35: 5; copy number 36: 10; copy number 37: 8; copy number 38: 8; copy number 41: 5; copy number 43: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A3M1-01A-11D-A227-01): tumor purity 0.8, ploidy 3.68, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:29,306,778–29,595,688, 4 genes (within-gene range 0–2): GAPDHP69, AL596092.1, MTUS2-AS1, SLC7A1.
- chr13:31,311,289–32,299,125, 10 genes (within-gene range 0–2): ANKRD26P4, AL161616.2, AL161616.1, RXFP2, AL138708.1, FRY, EEF1DP3, AC002525.1, Metazoa_SRP, FRY-AS1.
- chr17:33,013,087–34,174,964, 1 gene (within-gene range 0–2): ASIC2.
- chr17:33,529,787–34,363,233, 27 genes: AA06, AC011824.3, AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3, AC024614.4, AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1.
- chr17:69,577,251–70,135,608, 7 genes (within-gene range 0–5): LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 519 genes in 53 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:148,567,378–149,411,613, 13 genes, copy number 10: SNRPEP6, RPSAP40, UST, UST-AS1, UST-AS2, AL603766.1, AL031056.1, TAB2, TAB2-AS1, AL031056.2, RN7SL234P, FABP12P1, SUMO4.
- chr8:76,966,768–77,537,290, 4 genes, copy number 9: MIR3149, PEX2, HIGD1AP18, AC062004.1.
- chr8:84,678,798–85,087,186, 6 genes, copy number 11: PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1.
- chr8:96,126,967–100,350,707, 79 genes, copy number 10–12 (broad region; genes not listed).
- chr8:100,755,099–102,154,725, 37 genes, copy number 9: Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3, GRHL2, AP001207.2, AP001207.1, NCALD, AP000426.1, AP001329.1, PDCL3P2, MIR5680, AP001328.1.
- chr8:107,499,773–109,537,207, 22 genes, copy number 9 (within-gene range 6–9): AC091010.1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5.
- chr8:110,334,743–112,148,825, 15 genes, copy number 9: AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P.
- chr8:115,950,511–116,944,487, 10 genes, copy number 9: LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD.
- chr9:90,921,990–91,361,918, 10 genes, copy number 27: AL162585.1, AL355607.1, AL355607.2, AL158071.3, AL158071.2, LINC00484, LINC00484, AL158071.1, AL158071.4, AUH.
- chr9:110,190,048–110,337,884, 3 genes, copy number 31: C9orf152, TXN, TXNDC8.
- chr9:127,885,321–127,940,952, 5 genes, copy number 24: ST6GALNAC6, ST6GALNAC4, PIP5KL1, AL157935.1, DPM2.
- chr9:128,920,966–129,260,575, 15 genes, copy number 10 (within-gene range 3–10): PHYHD1, AL672142.1, DOLK, NUP188, AL592211.1, SH3GLB2, MIGA2, AL592211.2, DOLPP1, CRAT, AL158151.2, PTPA, AL158151.3, AL158151.4, IER5L.
- chr9:131,782,570–132,079,867, 4 genes, copy number 25: EIF4A1P3, AL160271.1, AL160271.2, MED27.
- chr12:54,682,973–54,896,008, 3 genes, copy number 17–31: AC079310.1, VDAC1P5, MUCL1.
- chr12:57,475,445–58,813,060, 50 genes, copy number 29 (within-gene range 4–29): MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388.
- chr12:64,404,392–64,502,114, 4 genes, copy number 24 (within-gene range 4–24): XPOT, AC135279.2, AC135279.3, TBK1.
- chr12:65,589,111–65,966,291, 8 genes, copy number 38 (within-gene range 5–38): LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1.
- chr12:66,292,683–66,343,643, 2 genes, copy number 18: RN7SKP166, HELB.
- chr12:68,746,125–69,460,724, 21 genes, copy number 11–37 (within-gene range 11–39): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373.
- chr12:70,180,338–70,637,440, 9 genes, copy number 30: LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1.
- chr12:71,034,122–72,186,618, 20 genes, copy number 19–41 (within-gene range 4–41): AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1.
- chr12:73,648,666–73,846,188, 4 genes, copy number 15–37: AC087879.1, RNU6-1012P, LINC02445, U8.
- chr12:78,793,526–79,778,451, 11 genes, copy number 25–41 (within-gene range 4–41): AC068993.1, AC068993.2, SYT1, AC090709.1, AC027288.3, MIR1252, AC027288.2, AC027288.1, NOP56P3, PAWR, AC073569.2.
- chr12:82,673,070–83,661,719, 6 genes, copy number 29–35: AC091214.1, TMTC2, RNU6-977P, RPL6P25, AC090680.1, AC093025.1.
- chr12:84,448,625–85,036,277, 5 genes, copy number 16: AC087888.1, AC093027.1, SLC6A15, AC128657.1, TSPAN19.
- chr12:86,599,578–87,170,429, 3 genes, copy number 23 (within-gene range 4–23): AC010196.1, AC079597.1, RPL23AP68.
- chr12:88,057,876–88,199,887, 2 genes, copy number 15: AC091516.1, TMTC3.
- chr12:89,544,203–89,709,300, 3 genes, copy number 19: AC025034.2, AC025034.1, ATP2B1.
- chr12:92,421,531–92,929,331, 6 genes, copy number 20 (within-gene range 4–20): AC063949.2, LINC02397, AC063949.1, PLEKHG7, EEA1, AC026111.1.
- chr12:94,834,147–95,073,628, 4 genes, copy number 11–43 (within-gene range 7–43): KRT19P2, MIR492, NDUFA12, NR2C1.
- chr12:95,438,737–95,942,635, 13 genes, copy number 14–25: RNU6-735P, AC018475.1, METAP2, USP44, PGAM1P5, Y_RNA, NTN4, AC090001.1, RNU6-247P, LINC02410, SNRPF, CCDC38, AC090001.2.
- chr12:96,900,697–97,598,415, 9 genes, copy number 22–34 (within-gene range 4–34): EEF1A1P33, NEDD1, Y_RNA, AC007656.2, AC007656.1, AC007656.3, AC007656.4, LINC02409, RMST.
- chr12:97,530,656–97,564,327, 8 genes, copy number 22: AC018659.4, AC018659.3, AC018659.1, AC018659.7, AC018659.5, AC018659.8, MIR135A2, AC018659.6.
- chr12:98,417,896–98,516,422, 5 genes, copy number 30: RNU4-41P, AC008055.2, SLC9A7P1, LINC02453, TMPO-AS1.
- chr12:98,794,485–99,105,011, 4 genes, copy number 11: AC008126.1, AC069437.1, RNA5SP366, AC117377.1.
- chr12:100,473,708–101,128,641, 6 genes, copy number 30 (within-gene range 4–30): NR1H4, AC010200.1, GAS2L3, PIGAP1, ANO4, AC138360.1.
- chr12:101,066,734–103,768,858, 60 genes, copy number 16–29: SNX5P2, SLC5A8, RNU6-768P, AC079953.1, UTP20, ARL1, AC063948.1, RNU6-1068P, RPS27P23, Y_RNA, RNU5E-5P, RNA5SP367, SPIC, MYBPC1, AC117505.1, AC010205.1, CHPT1, RNY1P16, SYCP3, GNPTAB, RNU6-101P, AC063950.1, RNA5SP368, RNU6-172P, RNA5SP369, RNU6-1183P, HSPE1P4, DRAM1, AC084398.2, AC084398.1, AC079907.2, NENFP2, WASHC3, AC079907.1, NUP37, PARPBP, PMCH, HELLPAR, RN7SL793P, AC093023.1, LINC02456, IGF1, AC010202.1, LINC00485, PAH, AC026108.1, ASCL1, AC026108.2, AC068643.1, AC068643.2, C12orf42, AC084364.1, AC084364.2, AC084364.3, LINC02401, STAB2, U8, AC025265.2, AC025265.3, AC025265.1.
- chr12:107,650,789–107,912,620, 12 genes, copy number 9–21: Y_RNA, PWP1, AC007622.1, PRDM4, AC007622.2, ASCL4, AC126177.3, AC126177.5, AC126177.2, AC126177.4, AC126177.6, AC126177.1.
- chr17:65,528,563–65,641,033, 2 genes, copy number 9: AXIN2, AC004805.1.
- chr17:65,644,308–65,655,395, 2 genes, copy number 9: AC004805.3, AC004805.2.

Autosomal genes at a single copy (total copy number 1): 475. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
